MMRF case MMRF_2383 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/cfccb7e5-b75f-4507-90d0-4daa457ced92

Demographics
Sex at birth: male; Age at index: 64 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 64.8 years (23,675 days); ISS stage: II; Days to last known disease status: 527 days (1.4 years); Days to last follow up: 527 days (1.4 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 74 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 126 days; Days to treatment end: 126 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 127 days; Days to treatment end: 127 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 235 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -12: M Protein 7.66 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 27.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.19 mg/dL; Immunoglobulin G 93 g/L; Immunoglobulin A 0.27 g/L; Immunoglobulin M 0.13 g/L; Beta 2 Microglobulin 5.32 µg/mL; Lactate Dehydrogenase 2.38 µkat/L; Hemoglobin 4.65 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 2.28 ×10⁹/L; Platelets 261 ×10⁹/L; Creatinine 85.7 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.28 mmol/L; Albumin 16 g/L; Total Protein 12 g/dL; Glucose 5.67 mmol/L; C-Reactive Protein 0.256 mg/dL.
- Day 88: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.08 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.93 mg/dL; Immunoglobulin G 10.2 g/L; Immunoglobulin A 0.44 g/L; Immunoglobulin M 0.64 g/L; Beta 2 Microglobulin 1.61 µg/mL; Lactate Dehydrogenase 2.58 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 1.76 ×10⁹/L; Platelets 257 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.3 mmol/L; Albumin 39 g/L; Total Protein 7.2 g/dL; Glucose 5.83 mmol/L.
- Day 179: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.093 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.148 mg/dL; Immunoglobulin G 10.8 g/L; Immunoglobulin A 0.81 g/L; Immunoglobulin M 0.47 g/L; Lactate Dehydrogenase 2.63 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 126 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.33 mmol/L; Albumin 38 g/L; Total Protein 6.9 g/dL; Glucose 6.44 mmol/L.
- Day 240: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.21 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.62 mg/dL; Immunoglobulin G 10.9 g/L; Immunoglobulin A 0.48 g/L; Immunoglobulin M 0.64 g/L; Beta 2 Microglobulin 1.62 µg/mL; Lactate Dehydrogenase 2.23 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.28 ×10⁹/L; Platelets 161 ×10⁹/L; Creatinine 64.5 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.25 mmol/L; Albumin 39 g/L; Total Protein 7.4 g/dL; Glucose 9.63 mmol/L.
- Day 331: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.82 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.29 mg/dL; Immunoglobulin G 12.3 g/L; Immunoglobulin A 0.57 g/L; Immunoglobulin M 0.38 g/L; Beta 2 Microglobulin 1.39 µg/mL; Lactate Dehydrogenase 2.47 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.43 ×10⁹/L; Platelets 153 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 7.4 g/dL; Glucose 5.67 mmol/L.
- Day 435: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.313 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.196 mg/dL; Immunoglobulin G 13.5 g/L; Immunoglobulin A 0.92 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 2.13 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 143 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.35 mmol/L; Albumin 37 g/L; Total Protein 7.2 g/dL; Glucose 4.62 mmol/L.
- Day 527 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.49 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.22 mg/dL; Immunoglobulin G 17.6 g/L; Immunoglobulin A 1.68 g/L; Immunoglobulin M 0.47 g/L; Beta 2 Microglobulin 1.64 µg/mL; Lactate Dehydrogenase 2.4 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.54 ×10⁹/L; Platelets 128 ×10⁹/L; Creatinine 71.6 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.25 mmol/L; Albumin 40 g/L; Total Protein 8.2 g/dL; Glucose 6.66 mmol/L.

Other clinical attributes
- Day -12: Weight: 84 kg; Height: 175 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2383_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -12 days.
- Sample MMRF_2383_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -12 days.
